Somatic mutation profile of tumor specimen TCGA-D1-A16S-01A (aliquot TCGA-D1-A16S-01A-11D-A12J-09) from TCGA case TCGA-D1-A16S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 70.3 years (25,690 days).
Specimen TCGA-D1-A16S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 206abc34-30d2-4012-b911-51babe025914.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16S-10A (Blood Derived Normal), aliquot TCGA-D1-A16S-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71440490-da2d-4ef8-b553-a4c7182263a0

The open-access MAF lists 57 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 8, Nonsense Mutation 4, Splice Site 3, Intron 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1625A>C p.E542A | Missense Mutation (SNP) | VAF 387/497 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 48/71 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61659439; called by muse, mutect2
- ADGRA1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs199841510, COSV66925412; called by muse, mutect2, varscan2
- BRD7 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 410/902 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs903645210, COSV67159761; called by muse, mutect2, varscan2
- BTNL3 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 176/516 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV61565639; called by muse, mutect2, varscan2
- C1QTNF5 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60991253; called by muse, mutect2, varscan2
- CCAR1 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 146/382 reads (38%) | catalogued as COSV56272726; called by muse, mutect2, varscan2
- CCN3 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV52384967; called by muse, mutect2, varscan2
- CCNB3 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV52078147; called by muse, mutect2, varscan2
- COQ10A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV57525667; called by muse, mutect2, varscan2
- CSNK2A1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 246/530 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV53937059; called by muse, mutect2, varscan2
- ERMN | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 143/355 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV68075235, COSV68075608; called by muse, mutect2, varscan2
- GLMN | c.1689C>A p.F563L | Missense Mutation (SNP) | VAF 231/591 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as COSV64861351; called by muse, mutect2, varscan2
- GLMN | c.1688T>A p.F563Y | Missense Mutation (SNP) | VAF 223/578 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.541); catalogued as rs761180709, COSV64861355; called by muse, mutect2, varscan2
- GPR171 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV56392241; called by muse, mutect2, varscan2
- GUCA1C | c.205-1G>A p.X69_splice | Splice Site (SNP) | VAF 28/357 reads (8%) | catalogued as COSV53755465; called by muse, mutect2
- HAUS7 | c.477C>A p.S159R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57850610; called by muse, mutect2, varscan2
- HPF1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV66422699; called by muse, mutect2, varscan2
- IFT52 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 310/631 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65975821; called by muse, mutect2, varscan2
- ILDR1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 132/214 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV56551849, COSV56552740; called by muse, mutect2, varscan2
- KCNH2 | c.3326C>G p.S1109C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as COSV51220235; called by muse, mutect2
- LIMK2 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 168/250 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.53); catalogued as rs201466946, COSV59182694; called by muse, mutect2, varscan2
- LRFN5 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs571352632, COSV53270382; called by muse, mutect2, varscan2
- MRPL42 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100696604, COSV62355587, COSV62357065; called by muse, mutect2
- PCDHB3 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.326); catalogued as COSV50611441; called by muse, mutect2, varscan2
- PEF1 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs761145394, COSV65483609; called by muse, mutect2
- PLEKHG4B | c.3223C>T p.R1075W (on ENST00000283426; = p.R1431W on NM_052909.5) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761248043, COSV52052880; called by muse, mutect2, varscan2
- QPCT | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 180/344 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs200573148, COSV58120267; called by muse, mutect2, varscan2
- RBP5 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs1167366282, COSV56939441; called by muse, mutect2, varscan2
- RIOK2 | c.1481C>A p.S494* | Nonsense Mutation (SNP) | VAF 98/373 reads (26%) | catalogued as COSV51613257, COSV51614577; called by muse, mutect2, varscan2
- RYR2 | c.11711G>A p.R3904Q | Missense Mutation (SNP) | VAF 46/648 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1374006844, COSV63684716; called by muse, mutect2
- SACS | c.12517A>G p.M4173V | Missense Mutation (SNP) | VAF 12/438 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV66545360; called by muse, mutect2
- SCN8A | c.5650G>A p.E1884K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs147578087, COSV61989984; called by muse, mutect2, varscan2
- SEMA3C | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.266); catalogued as rs536937172, COSV54853527; called by muse, mutect2, varscan2
- SIGLEC6 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 231/529 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200633036; called by muse, mutect2, varscan2
- SLC24A2 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 91/130 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53872541; called by muse, mutect2, varscan2
- SLC47A1 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54503442; called by muse, mutect2, varscan2
- SZT2 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 89/575 reads (15%) | catalogued as COSV60290698; called by muse, mutect2, varscan2
- TRAF5 | c.544-1G>C p.X182_splice | Splice Site (SNP) | VAF 16/424 reads (4%) | catalogued as COSV54824189; called by muse, mutect2
- WAC | c.1437+1G>C p.X479_splice | Splice Site (SNP) | VAF 23/293 reads (8%) | catalogued as COSV100610959, COSV61569127, COSV61569197; called by muse, mutect2
- ZFC3H1 | c.5150T>C p.L1717P | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV66435164; called by muse, mutect2, varscan2
- ZNF273 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV60398332; called by muse, mutect2
- ZRANB1 | c.1855C>G p.L619V | Missense Mutation (SNP) | VAF 114/301 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs768428363, COSV61476442; called by muse, mutect2, varscan2
- NAV2 | c.4524del p.N1509Tfs*49 (on ENST00000396087 / NM_001244963.2; = p.N1486Tfs*49 on NM_145117.5) | Frame Shift Del (DEL) | VAF 211/398 reads (53%) | called by mutect2, pindel, varscan2
- TENM3 | c.6273del p.Q2091Hfs*22 | Frame Shift Del (DEL) | VAF 44/95 reads (46%) | called by mutect2, pindel, varscan2
- ADAP1 | c.153C>T p.I51= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV56216575; called by muse, mutect2, varscan2
- AGAP1 | c.2127A>G p.E709= (on ENST00000304032 / NM_001037131.3; = p.E656= on NM_014914.5) | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1380763828, COSV58336476; called by muse, mutect2, varscan2
- CPAMD8 | c.405C>G p.L135= (on ENST00000651564; = p.L88= on NM_015692.5) | Silent (SNP) | VAF 34/896 reads (4%) | catalogued as COSV52238374; called by muse, mutect2
- ICAM5 | c.999C>T p.S333= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV55748713; called by muse, mutect2, varscan2
- PCDH19 | c.1320C>T p.T440= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as rs1181553650, COSV55269249; called by muse, mutect2
- RANBP9 | c.2169A>G p.T723= | Silent (SNP) | VAF 61/167 reads (37%) | catalogued as COSV50584454; called by muse, mutect2, varscan2
- SARAF | c.144C>T p.H48= | Silent (SNP) | VAF 146/214 reads (68%) | catalogued as COSV56358103; called by muse, mutect2, varscan2
- VNN1 | c.960C>T p.A320= | Silent (SNP) | VAF 54/301 reads (18%) | catalogued as COSV63390725; called by muse, mutect2, varscan2
- LRRFIP1 | c.154-1747G>C | Intron (SNP) | VAF 241/667 reads (36%) | catalogued as COSV55255233; called by muse, mutect2, varscan2
- MRI1 | c.548-133C>G | Intron (SNP) | VAF 87/114 reads (76%) | catalogued as COSV50005218; called by muse, mutect2, varscan2
